Somatic mutation profile of tumor specimen TCGA-2G-AAGM-01A (aliquot TCGA-2G-AAGM-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGM, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Yolk sac tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 51.2 years (18,696 days).
Specimen TCGA-2G-AAGM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 729c9fe3-713d-44ac-9c3b-6beb18a6a575.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGM-10A (Blood Derived Normal), aliquot TCGA-2G-AAGM-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3baa2fce-c04a-424d-a24d-62e3e75b10e5

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Del 3, In Frame Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD50 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV72385950; called by muse, mutect2, varscan2
- CAMKK1 | c.957del p.E320Rfs*66 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | catalogued as COSV99340569; called by mutect2, pindel, varscan2
- CCPG1 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs1319649300; called by muse, mutect2
- DMD | c.4000G>A p.G1334R | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs146880270, COSV63780212; called by muse, mutect2, varscan2
- GOLGA2 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV101363245; called by muse, mutect2
- MUC16 | c.5007_5009del p.R1669del | In Frame Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs759930204; called by pindel, varscan2
- PDLIM5 | c.505G>C p.V169L | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.044); catalogued as COSV58752727; called by muse, mutect2, varscan2
- TRPV6 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753833631, COSV63892179; called by muse, mutect2, varscan2
- AKAP9 | c.5890del p.T1964Lfs*13 (on ENST00000359028; = p.T1932Lfs*13 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/180 reads (16%) | called by mutect2, pindel, varscan2
- AUTS2 | c.2493T>G p.D831E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CCDC54 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 107/296 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXA1 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PCDH7 | c.2804A>G p.K935R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- S1PR5 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SLC25A46 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- SMURF1 | c.2201_2202del p.Y734* | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by pindel, varscan2
- SP100 | c.1787A>G p.E596G | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.134); called by muse, mutect2
- TNS3 | c.2914A>T p.S972C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- TPST1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TYK2 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP1A4 | c.2880A>G p.L960= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as rs1399565697; called by muse, mutect2, varscan2
- CDR1 | c.480C>T p.S160= | Silent (SNP) | VAF 102/401 reads (25%) | catalogued as rs146276960, COSV100983394, COSV65164211; called by muse, mutect2, varscan2
- PIK3C2B | c.3540C>T p.S1180= | Silent (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- PMS2 | c.2433C>A p.A811= | Silent (SNP) | VAF 73/215 reads (34%) | called by muse, mutect2, varscan2
- POTEC | c.336C>T p.S112= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as rs754562772, COSV62800655, COSV62800759; called by muse, mutect2
- TNIK | c.1554G>T p.L518= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- U82695.1 | n.1798G>A | RNA (SNP) | VAF 45/236 reads (19%) | catalogued as rs988373065; called by muse, mutect2, varscan2
- Z82198.2 | chr22:33166826 A>G | 3'Flank (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
